Somatic mutation profile of tumor specimen MP2PRT-PAUFKI-TMP1-A (aliquot MP2PRT-PAUFKI-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUFKI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,380 days).
Specimen MP2PRT-PAUFKI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb241444-3de8-4737-9cd6-b7793738f0c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUFKI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUFKI-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0aad49b6-2871-48be-8feb-cdc21a93280b

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as rs397507539, CM044253, CM122802, CX097234, COSV61006286; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CCDC168 | c.12559C>T p.P4187S | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.1); catalogued as rs1419324523; called by muse, mutect2
- CREBBP | c.4262G>A p.C1421Y | Missense Mutation (SNP) | VAF 82/243 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200616542, COSV52138366, COSV99269455; called by muse, mutect2, varscan2
- LINC02218 | c.40T>C p.F14L | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1317374590; called by muse, mutect2, varscan2
- MASP2 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as rs199847106; called by muse, mutect2
- PGC | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 104/402 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs768314678, COSV63123835; called by muse, mutect2, varscan2
- RBM6 | c.3013C>T p.R1005* | Nonsense Mutation (SNP) | VAF 55/126 reads (44%) | catalogued as rs758252047, COSV56481544; called by muse, mutect2, varscan2
- CAMTA1 | c.1432G>C p.E478Q | Missense Mutation (SNP) | VAF 130/410 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FLT3 | c.1779T>A p.D593E | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MMP14 | c.896C>A p.T299N | Missense Mutation (SNP) | VAF 92/408 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SALL3 | c.423C>A p.D141E | Missense Mutation (SNP) | VAF 66/1092 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- SLC5A11 | c.878T>A p.V293D | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNA5 | c.1392C>T p.F464= | Silent (SNP) | VAF 121/402 reads (30%) | catalogued as COSV52906744; called by muse, mutect2, varscan2
- NACC2 | c.1245C>T p.N415= | Silent (SNP) | VAF 20/237 reads (8%) | catalogued as rs139916490; called by muse, mutect2
- AP003071.5 | c.*465G>A | 3'UTR (SNP) | VAF 30/312 reads (10%) | catalogued as rs1000510125; called by muse, mutect2
